Somatic mutation profile of tumor specimen 0DFO1F from CCDI case PBBSDA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 6.5 years (2,379 days).
Specimen 0DFO1F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adbb1bd7-5ce8-49dd-b159-215e69f54aab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFO12 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47f92595-326b-447f-8b81-981b4cc9fdd3

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, 5'UTR 2, Intron 2, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 96/572 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200966429, COSV99907600; called by muse, varscan2
- CACHD1 | c.2130C>G p.H710Q | Missense Mutation (SNP) | VAF 162/817 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.095); catalogued as COSV99262776; called by muse, mutect2, varscan2
- CACNA1B | c.6976G>A p.A2326T | Missense Mutation (SNP) | VAF 150/461 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs369460375; called by muse, varscan2
- CDCA4 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1345604345; called by muse, mutect2, varscan2
- CFAP57 | c.3622C>T p.R1208C (on ENST00000372492 / NM_001378189.1; = p.R1241C on NM_001195831.3) | Missense Mutation (SNP) | VAF 161/757 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1056388001, COSV100993903; called by muse, mutect2, varscan2
- CYTH2 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 233/877 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs753332499; called by muse, mutect2, varscan2
- EPHB2 | c.1994G>A p.R665Q (on ENST00000400191 / NM_001309193.2; = p.R666Q on NM_004442.7) | Missense Mutation (SNP) | VAF 160/727 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs534341737, COSV101006668, COSV65859934; called by muse, varscan2
- FMO2 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 187/1136 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs368153993; called by muse, mutect2, varscan2
- IL1B | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 146/611 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as rs746237682, COSV99641923; called by muse, mutect2, varscan2
- NAV3 | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 135/815 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV57076442; called by muse, mutect2, varscan2
- OPTN | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 102/625 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs201896586, COSV53811027, COSV53812355; called by muse, mutect2, varscan2
- OR4C16 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 185/709 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2, varscan2
- OSTF1 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 131/501 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as rs1015895778; called by muse, mutect2, varscan2
- OVOL3 | c.203C>A p.S68* (on ENST00000585332; = p.S44* on NM_001302757.1) | Nonsense Mutation (SNP) | VAF 185/834 reads (22%) | catalogued as rs1451920030; called by muse, mutect2, varscan2
- PDE4D | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 388/1153 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as rs756880197, COSV101550395; called by muse, mutect2, varscan2
- SERPINC1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 414/943 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs377588972; called by muse, varscan2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 415/1003 reads (41%) | catalogued as rs567805129; called by mutect2, varscan2
- TTBK1 | c.2863A>G p.S955G | Missense Mutation (SNP) | VAF 103/519 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs371142001; called by muse, mutect2, varscan2
- TUBA3D | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 133/735 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs377460015; called by muse, mutect2, varscan2
- CALB1 | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 93/902 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- CD101 | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 172/878 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CSMD3 | c.4715A>G p.E1572G (on ENST00000297405 / NM_001363185.1; = p.E1468G on NM_052900.3) | Missense Mutation (SNP) | VAF 144/1188 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FGF14 | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 141/879 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- FREM1 | c.5254G>C p.V1752L | Missense Mutation (SNP) | VAF 355/1267 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- KBTBD2 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 127/797 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCMDC2 | c.1357C>G p.P453A | Missense Mutation (SNP) | VAF 201/1427 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NSDHL | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 186/374 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- OVGP1 | c.983G>T p.W328L | Missense Mutation (SNP) | VAF 302/746 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLCB4 | c.3416T>C p.V1139A | Missense Mutation (SNP) | VAF 130/977 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POM121L2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 173/716 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRIM1 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 153/1148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIMS1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 289/707 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RRP7A | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 68/640 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, mutect2
- TBX19 | c.628A>C p.N210H | Missense Mutation (SNP) | VAF 175/1255 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.4851G>T p.G1617= | Silent (SNP) | VAF 131/573 reads (23%) | catalogued as rs763040657; called by muse, mutect2, varscan2
- AKAP3 | c.2142A>G p.L714= | Silent (SNP) | VAF 77/565 reads (14%) | called by muse, mutect2, varscan2
- AL662899.2 | c.252C>T p.H84= | Silent (SNP) | VAF 163/721 reads (23%) | catalogued as rs761163913; called by muse, mutect2, varscan2
- ASIP | c.324C>T p.C108= | Silent (SNP) | VAF 119/901 reads (13%) | catalogued as COSV66588245; called by muse, mutect2, varscan2
- C12orf56 | c.1278G>A p.E426= (on ENST00000543942 / NM_001170633.2; = p.E266= on NM_001099676.3) | Silent (SNP) | VAF 163/1111 reads (15%) | called by muse, mutect2, varscan2
- CDK5RAP3 | c.795T>C p.D265= | Silent (SNP) | VAF 136/862 reads (16%) | called by muse, varscan2
- HNRNPM | c.72G>A p.A24= | Silent (SNP) | VAF 79/648 reads (12%) | called by muse, mutect2, varscan2
- MAP6D1 | c.66C>T p.S22= | Silent (SNP) | VAF 94/500 reads (19%) | catalogued as rs1170944742; called by muse, mutect2, varscan2
- RYR2 | c.14232C>T p.L4744= | Silent (SNP) | VAF 234/1652 reads (14%) | catalogued as rs777371415; called by muse, mutect2, varscan2
- SLITRK1 | c.897C>T p.A299= | Silent (SNP) | VAF 127/871 reads (15%) | called by muse, mutect2, varscan2
- TFDP1 | c.504C>T p.R168= | Silent (SNP) | VAF 146/860 reads (17%) | catalogued as rs374253994; called by muse, mutect2, varscan2
- VPS13B | c.3333G>T p.P1111= | Silent (SNP) | VAF 170/1350 reads (13%) | called by muse, varscan2
- F2RL2 | c.-31A>C | 5'UTR (SNP) | VAF 59/383 reads (15%) | called by muse, mutect2, varscan2
- GABRB3 | c.545-54G>A | Intron (SNP) | VAF 88/411 reads (21%) | catalogued as rs112553936; called by muse, mutect2, varscan2
- HNF1B | c.*108C>T | 3'UTR (SNP) | VAF 154/765 reads (20%) | catalogued as rs571805143; called by muse, mutect2, varscan2
- PID1 | c.-59G>T | 5'UTR (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2, varscan2
- RAC1 | c.226-1449G>C | Intron (SNP) | VAF 104/652 reads (16%) | called by muse, mutect2, varscan2
